Gene-level copy-number profile of tumor specimen TCGA-33-A4WN-01A from TCGA case TCGA-33-A4WN, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 61.0 years (22,268 days).
Specimen TCGA-33-A4WN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.cde16bca-bad2-417e-a21a-0e24ce968ce8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-33-A4WN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/21352aac-a931-4be7-97d8-640c73563812

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 9,953; copy number 3: 3,507; copy number 4: 36,894; copy number 5: 388; copy number 6: 6,127; copy number 7: 502; copy number 8: 457; copy number 9: 850; copy number 10: 4; copy number 11: 307; copy number 12: 629; copy number 13: 81; copy number 14: 3; copy number 18: 112.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-33-A4WN-01A-11D-A25M-01): tumor purity 0.39, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,979 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:109,915,976–198,222,513, 1,591 genes, copy number 9–12 (broad region; genes not listed).
- chr4:60,750,575–62,818,794, 18 genes, copy number 9: LINC02496, AC105420.1, MIR548AG1, LINC02271, ADGRL3, RPL17P19, AC020741.1, AC108161.1, Y_RNA, ADGRL3-AS1, RPS15AP17, AC007511.1, RPL21P47, AC105313.1, AC074087.2, AC074087.1, HMGN1P11, EXOC5P1.
- chr5:12,297,399–24,644,978, 153 genes, copy number 9–14 (broad region; genes not listed).
- chr8:34,784,028–43,544,057, 193 genes, copy number 13–18 (broad region; genes not listed).
- chr17:61,354,763–62,320,189, 24 genes, copy number 9: AC005746.3, AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875, TBX4, AC005901.1, NACA2, BRIP1, INTS2, Y_RNA, MED13, AC018628.1, RN7SL800P, AC018628.2, Y_RNA, Y_RNA, POLRMTP1, AC053481.3, AC053481.4, TBC1D3P2, AC053481.2, AC053481.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
